Surgical pathology report (de-identified scan), TCGA case TCGA-S7-A7WU, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site University Hospital Motol, specimen TCGA-S7-A7WU-01A (Primary Tumor).

[page 1 of 2]
Gross:

Left adrenal gland with tumors with dimension 50x48x25 mm, weight 30 g. Major part of the adrenal gland is replaced by tumor (42x30x22 mm), on cut grey with focal hemorrhages, in the second part ochre yellow nodule (23x15x15 mm). The remaining adrenal tissue measures 10x5x5 mm with yellow color.

Micro:

In blocks A and G diffusely and nodularly hyperplastic adrenal cortex with focal hypolipidosis. Encapsulated intracapsular proliferation of the adrenal cortex sporadically (block E). In block H, in the adipose tissue bordered patch of symmetric slightly bruised adrenocortical tissue.

In blocks B and C were also found these cortical structures; further parts of the excisions is constituted by solidly alveolarly shaped pheochromocytoma from smaller and moderately large cells, with focal diffuse growth, focally with spindle cell component, without necrosis. Isolated tumor was examined in blocks D-F, is shows moderate to high cellularity. Focal profound cellular atypias. No mitoses were found. No invasion into vessels or capsular invasion was found.

Immunohistochemic examination:

S100 protein sustentacular cells are missed in large parts of pheochromocytoma. MIB1 activity is in both procured lesions minimal <1% positive nuclei. Chromogranin A – pheochromocytoma strong positive, adrenocortical structures negative

Synaptophysin – pheochromocytoma strong positive, adrenocortical structures negative

PASS:

Large nests or diffuse growth (>10% of tumor volume) 2

Central (middle of large nests) or confluent tumor necrosis

High cellularity 2

Cellular monotony

Tumor cell spindling (even if focal) 2

Mitotic figures >3/10 HPF

Atypical mitotic figure(s)

Extension into adipose tissue

Vascular invasion

Capsular invasion

Profound nuclear pleomorphism 1

Nuclear hyperchromasia 1

ICD-O-3
Pheochromocytoma, malignant
8700/3
Site Adrenal gland C74.9
JW 10/9/13

[page 2 of 2]
Total 8

Procurement date:

Confirmation date:

Criteria	W 9/11/13	Yes	No
Prior Malignancy History	Thyroid - p16	✓	✓

Source: NCI Genomic Data Commons file 559c7ca2-2c04-4b98-a0ae-981c57782bdf (TCGA-S7-A7WU.46CA3237-34DE-482C-8311-C63D1547BB26.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).